Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SP-01A (Primary Tumor).

[page 1 of 3]
Result Type: Surgical Pathology Report

Performed By:

**Encounter
info:**

Surgical Pathology Report

Final

ICD O-3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS
C64.9
JW 10/4/13

Surgical Pathology Report

REVISED REPORT

Clinic Number: Name:

Requested By:

DIAGNOSIS:

AMENDMENT REPORT

. This amendment is being performed to correct the AJCC pathologic stage grouping. The stage grouping will be changed to pT1b,N0 .

Procedure/laterality: Kidney, left, partial nephrectomy.

Histologic type: Papillary renal cell carcinoma, type 1.

Nuclear grade (Fuhrman, 1-4): 2 of 4.

Tumor size: 5.5 cm in greatest dimension.

Tumor site: Midportion left kidney.

Tumor focality: Unifocal.

Sarcomatoid features: Absent.

Tumor necrosis: Absent.

Microscopic tumor extension:

Extension into perinephric tissue: Not applicable.

Extension beyond Gerota's fascia: Not applicable.

Extension into renal sinus: Not applicable.

Extension into renal vein: Not applicable.

Extension into collecting system: Not applicable.

Extension into adrenal gland (if applicable): Not applicable.

Surgical margins: Negative.

Lymph-vascular invasion: Absent.

Lymph nodes: Not applicable.

Pathologic findings in nonneoplastic kidney: There is insufficient non-neoplastic kidney available for evaluation.

Pathologic staging: pT1b, N0.

Biorepository sample (if applicable): Positive for malignancy.

Block(s) containing malignancy suitable for additional testing:

A1-A6.

DIAGNOSIS COMMENT:

Frozen section diagnosis confirmed on permanent sections.

Representative sections shared with who concurs.

[page 2 of 3]
AMENDMENTS: (Previous Signout Date:
Revision Description:
See final report for amendment reason
....Original Diagnosis....
Procedure/laterality: Kidney, left, partial nephrectomy.
Histologic type: Papillary renal cell carcinoma, type 1.
Nuclear grade (Fuhrman, 1-4): 2 of 4.
Tumor size: 5.5 cm in greatest dimension.
Tumor site: Midportion left kidney.
Tumor focality: Unifocal.
Sarcomatoid features: Absent.
Tumor necrosis: Absent.
Microscopic tumor extension:
Extension into perinephric tissue: Not applicable.
Extension beyond Gerota's fascia: Not applicable.
Extension into renal sinus: Not applicable.
Extension into renal vein: Not applicable.
Extension into collecting system: Not applicable.
Extension into adrenal gland (if applicable): Not applicable.
Surgical margins: Negative.
Lymph-vascular invasion: Absent.
Lymph nodes: Not applicable.
Pathologic findings in nonneoplastic kidney: There is insufficient
non-neoplastic kidney available for evaluation.
Pathologic staging: pT2, NX.
Biorepository sample (if applicable): Positive for malignancy.
Block(s) containing malignancy suitable for additional testing:
A1-A6.

CLINICAL INFORMATION:
Left kidney mass.

SPECIMEN(S):
A:Left renal mass

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:
Intraoperative Pathologist(s):
A. Left renal mass, frozen section diagnosis:
A1) Papillary renal cell carcinoma.

GROSS DESCRIPTION:
Performed by
A. Received fresh labeled and "left renal mass".
Procedure: Partial nephrectomy.
Specimen laterality: Left.
Tumor site: Midportion of left kidney, as indicated in the
radiologic imaging.
Tumor size: 5.5 x 4.5 x 3.5 cm.

[page 3 of 3]
Tumor focality: Unifocal.

Gross extent of tumor:

Extension into perinephric tissue: Absent.

Extension beyond Gerota's fascia: Absent.

Extension into renal sinus: Not grossly apparent.

Extension into renal vein: Not grossly apparent.

Extension into collecting system: Not grossly apparent.

Adrenal gland: Absent.

Gross notes:

Gross tumor characteristics: Tan-yellow, centrally hemorrhagic, well-demarcated, solid mass with diffusely soft cut surfaces.

Kidney weight: 43 g.

Kidney dimensions: 5.5 x 4.5 x 3.5 cm.

Distance to margin: The tumor grossly appears to abut the inked parenchymal margin.

Lymph nodes: Absent.

Inking details: The parenchymal resection margin is inked black and the margin is designated by the surgeon.

Biorepository sample submitted: Yes, see block key.

Other: Representative sections from the cut surface of the tumor are submitted for frozen section in one block.

Block key for specimen A:

A1) Representative sections from cut surface of tumor, submitted for frozen section.

A2-A4) Additional sections of tumor in relation to inked parenchymal margin.

A5) Mirror image of tissue submitted for IRB study

A6) Section of tumor in relation to outermost surface (renal capsule).

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 8d1f1665-86bb-405b-bbdc-ddc2af77780f (TCGA-SX-A7SP.52507510-2117-4005-8BB4-234DDFC071ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).